Somatic mutation profile of tumor specimen TARGET-10-PANUYZ-09A (aliquot TARGET-10-PANUYZ-09A-01D) from TARGET case TARGET-10-PANUYZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (676 days).
Specimen TARGET-10-PANUYZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca34ca0f-3cd7-4178-b9cc-d425a8cbfb5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANUYZ-14A (Bone Marrow Normal), aliquot TARGET-10-PANUYZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00cb3ae0-72c9-455e-93fc-38e5cdbf4588

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 3, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCS | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55459505; called by muse, mutect2, varscan2
- PLCD3 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779191448; called by muse, mutect2, varscan2
- UGT2B7 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as rs373528265; called by muse, mutect2, varscan2
- CENPB | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.159); called by muse, mutect2
- CPZ | c.1189dup p.Q397Pfs*24 (on ENST00000360986 / NM_001014447.3; = p.Q386Pfs*24 on NM_003652.3) | Frame Shift Ins (INS) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- SEC14L5 | c.503A>C p.N168T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SRPRA | c.1523T>C p.F508S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF609 | c.1348C>A p.L450M | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- CIC | c.903G>A p.S301= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs769787910; called by muse, mutect2, varscan2
- INTS13 | c.1353G>A p.Q451= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- PADI1 | c.1737G>A p.A579= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs762129125; called by muse, mutect2, varscan2
- SLC8A2 | c.1320G>A p.A440= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1334571599, COSV99370296; called by muse, mutect2, varscan2
- VRTN | c.1947G>A p.T649= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs777175973, COSV56439410; called by muse, mutect2
- CTDSPL2 | c.1240-57T>C | Intron (SNP) | VAF 4/13 reads (31%) | catalogued as rs942882344; called by muse, mutect2
- PDCD6IPP1 | chr15:22744780 A>T | 3'Flank (SNP) | VAF 20/56 reads (36%) | called by muse, varscan2
- STAB1 | c.4810-44T>C | Intron (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- TAGAP | c.149-63T>C | Intron (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
